Surgical pathology report (de-identified scan), TCGA case TCGA-14-3477, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-3477-01A (Primary Tumor).

[page 1 of 4]
Document Type: AP Report
Document Date:
Document Status: Modified
Document Title: AP REPORT

*** Final Report ***

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. RIGHT TEMPORAL BRAIN LESION, RESECTION, FS1A, TP1A:
- GLIOBLASTOMA, WHO GRADE IV.
- SEE COMMENT.
2. RIGHT TEMPORAL BRAIN LESION, RESECTION:
- GLIOBLASTOMA, WHO GRADE IV.
- SEE COMMENT.

COMMENT:

This high grade astrocytoma shows abundant pseudopalisading type necrosis.

FISH studies for EGFR will be performed and the results will be issued in a separate report. Tissue will be sent for MGMT analysis and the results will be issued in a separate report.

SPECIMEN:

1. Right temporal brain lesion.
2. Right temporal brain lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

Right craniotomy for tumor resection. Right brain tumor.

GROSS DESCRIPTION:

Two specimens are received, each labeled with the patient's name and medical record number.

Specimen #1 is received fresh for intraoperative consultation and is labeled as "temporal brain lesion." The specimen consists of multiple

[page 2 of 4]
fragments of
soft tan tissue measuring in aggregate 2.0 x 1.5 x 0.3 cm. The
specimen is
submitted entirely for frozen section diagnosis and the contents of
the
cryoblock are transferred to cassette "FS1A." A touch prep is also
performed.

Specimen #2 is received in formalin and is labeled as "right
temporal brain
lesion." The specimen consists of multiple fragments of pink-tan
soft tissue
measuring in aggregate 2.5 x 1.5 x 0.3 cm. The specimen is
submitted entirely
in cassette "2A."

INTRAOPERATIVE CONSULTATION:

FS1A, TP1A: RIGHT TEMPORAL BRAIN LESION, BIOPSY (FROZEN SECTION,
TOUCH

PREPARATION): GLIOBLASTOMA.

Frozen Section results were communicated to the
surgical team

and were repeated back by

Pathologist: .

MICROSCOPIC DESCRIPTION:

Microscopic examination performed.

SPECIAL STAINS:

CD4	DONE
CD8	DONE
SV40	DONE
FISH	DONE
FISH	DONE
FISH	DONE
FISH	DONE

FLUORESCENCE IN SITU HYBRIDIZATION

SPECIMEN:

Brain, right temporal lesion.

CLINICAL HISTORY/REFERRING DIAGNOSIS:

Glioblastoma, WHO Grade IV.

GROSS DESCRIPTION:

Paraffin block 2A.

TEST PERFORMED/PROBES USED:

[page 3 of 4]
EGFR gene locus specific probe(7p12)
Chromosome 7 alpha satellite DNA specific probe(7p11.1-7q11.1)

PTEN gene locus specific probe 10q23
Chromosome 10 alpha satellite DNA specific probe (10p11.1-q11.1)

RESULTS:

NEGATIVE for EGFR gene amplification
nuc ish 7cen(D7Z1x2-10), 7p12(EGFRx2-10) [198/200]

NEGATIVE for chromosome 10q23 deletion
nuc ish(PTEN x 2-4), (D10Z1 x 2-4) [187/200]

INTERPRETATION:

Flourescence in situ hybridization was performed using the above listed DNA probes (). The probes were simultaneously hybridized to a section of the formalin-fixed paraffin-embedded tissue submitted for evaluation.

Of 200 interphase nuclei analyzed, 99% of cells were NEGATIVE for EGFR gene amplification. Positive and negative controls were appropriate. Correlation with clinical and other laboratory parameters is suggested.

Fluorescence in situ hybridization was performed using the above listed DNA probes (). The probes were simultaneously hybridized to a section of the formalin-fixed paraffin-embedded tissue submitted for evaluation.

Of 200 interphase nuclei analyzed, 93% demonstrated a normal number of signals for the PTEN probe which indicates the absence of deletion for chromosome 10q23. Correlation with clinical and other laboratory parameters is suggested.

COMMENT:

The results of this test should not be used alone as the sole basis for diagnosis and/or treatment. These results may, however, prove useful when used in conjunction with other diagnostic procedures and clinical evaluations.

[page 4 of 4]
Use of these results, in this manner, can be considered to fall within the scope of practice of medicine. This test was developed and its performance characteristics determined by the [REDACTED]. It has not been

FLUORESCENCE IN SITU HYBRIDIZATION

COMMENT:

cleared or approved by the U.S. Food and Drug Administration.

Medical Records

Page 3 (End of Report)

Source: NCI Genomic Data Commons file e8dd4098-7f3b-45a0-bf50-fb771f08b688 (TCGA-14-3477.EF5808A0-9573-44A7-90BB-A5273213302A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).